Surgical pathology report (de-identified scan), TCGA case TCGA-KN-8437, project TCGA-KICH (Kidney Chromophobe), tissue source site Harvard, specimen TCGA-KN-8437-01A (Primary Tumor).

[page 1 of 2]
Previous biopsies: 05-44224M RT: SUPERIOR TURBINATE & ANTERIOR NASAL SEPTUM.
04-43867M allograft renal biopsy
02-23164M ALLOGRAFT RENAL BIOPSY/is.
01-27641M TX KIDNEY BX/sr.
(and more)

DIAGNOSIS

Right kidney, radical nephrectomy:

Chromophobe renal cell carcinoma. see synoptic report.

Kidney: Nephrectomy, partial or radical Synopsis

MACROSCOPIC

Specimen Type: Right radical nephrectomy.

Focality: Unifocal mass.

Tumor Site

Greatest dimension: 3.0 cm.

Pathologic Complete Response (pCR): Not Applicable

MICROSCOPIC

Histologic Type:

Chromophobe renal cell carcinoma.

[page 2 of 2]
[REDACTED]

Histologic Grade: G1: Nuclei round, uniform, approximately 10 microns; nucleoli inconspicuous or absent.

EXTENT OF INVASION

Primary Tumor: pT1a: Tumor 4 cm or less in greatest dimension, limited to the kidney.

Regional Lymph Nodes: pNX: Cannot be assessed.

Lymph Nodes: None submitted.

Distant metastasis: pMX: Cannot be assessed.

Margins:

Margins uninvolved by invasive carcinoma.

Adrenal gland: Not present.

Venous invasion: Absent.

Comments: Colloidal iron stain shows focal granular cytoplasmic staining consistent with the above diagnosis. The tumor arises in an end stage kidney.

Clinical: Right renal mass.

Gross: The specimen is received fresh labeled with the patient's name [REDACTED] the medical record number and "right kidney", and consists of a laparoscopic radical nephrectomy specimen. The kidney with attached perinephric fat weighs 51 grams. The perinephric fat is inked in black and the specimen is preserved to reveal a well circumscribed tan and brown nodule measuring 3.0 x 3.0 x 1.5 cm. The nodule abuts the renal capsule but no invasion into perinephric fat is noted. Small cysts are noted within the cortex. The remainder of the kidney is grossly unremarkable. The renal mass is sectioned and a portion is taken for tissue bank. No adrenal gland is present. The specimen is represented as follows: A=vascular margin, B=ureter margin, C-F=tumor in tumor relation to kidney and perinephric fat, F=cystic areas and cortex and samples of cortex and medulla, G=section of grossly unremarkable perinephric fat.

[REDACTED]

Source: NCI Genomic Data Commons file 8373df6b-3fb7-47cb-816a-de613d4d42db (TCGA-KN-8437.9F926DDE-901C-4611-AEE6-3ECDE5A7C165.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).